Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A1NS, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A1NS-01A (Primary Tumor).

[page 1 of 3]
1CD-0-3

Adenocarcinoma, endometrioid, Nos 8380/3

Site: endometrium C54.1

2/24/11 lw

Surgical Pathology

SLIDE DISPOSITION:

DIAGNOSIS:

A. Abdomen, panniculectomy: Skin and subcutaneous tissue, 1720.0 grams identified grossly.

B. Uterus, bilateral ovaries and fallopian tubes; hysterectomy and

bilateral salpingo-oophorectomy: FIGO grade I (of III) endometrial

adenocarcinoma, endometrioid type, is identified forming a polypoid

mass (3.2 x 2.9 x 1.0 cm) located in the posterior uterine wall.

The tumor invades 0.3 cm into the myometrium (total wall thickness

1.8 cm). The tumor does not involve the endocervix.

Lymphovascular

space invasion is not identified. There is a single intramural

leiomyomata (0.6 cm in greatest dimension). Adenomyosis is present.

The bilateral ovaries and fallopian tubes are not involved.

Multiple (2 right, 0.8 cm and 1.2 cm in greatest dimension; 1 left,

1.4 cm in greatest dimension) paratubal cysts are identified.

C. Lymph nodes, right pelvic, lymphadenectomy: Multiple (23) right

pelvic lymph nodes are negative for tumor.

D. Lymph nodes, left pelvic, lymphadenectomy: Multiple (18) left

pelvic lymph nodes are negative for tumor.

With available surgical materials, [AJCC pT1N0] (7th edition, 2010).

[page 2 of 3]
This final pathology report is based on the gross/macrosopic examination and the frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

GROSS DESCRIPTION:

A. Received fresh labeled "pannus" is a 1720.0 gram portion of skin and subcutaneous tissue, without umbilicus. No lesions identified.

Gross only. Grossed by .

B. Received fresh labeled "uterus, right and left fallopian tubes and ovaries" is a 95.0 gram uterus with attached bilateral fallopian tubes and ovaries. The uterine serosa is smooth. There is a 3.2 x

2.9 x 1.0 cm polypoid mass in the posterior wall of the endometrial cavity, grossly invading 0.3 cm. The myometrial thickness is 1.8

cm. There is a single intramural leiomyoma (0.6 cm in greatest dimension). There is a 1.7 x 1.0 x 1.0 cm right ovary with a smooth

outer surface and a solid cut surface with a 4.2 x 0.5 cm right

fallopian tube which has multiple (2) paratubal cysts (0.8 cm and

1.2 cm in greatest dimension). There is a 1.8 x 1.1 x 0.9 cm left

ovary with a smooth outer surface and a solid cut surface with a 6.5

x 0.5 cm left fallopian tube with a 1.4 cm in greatest dimension

[page 3 of 3]
paratubal cyst. Representative sections are submitted.

C. Received fresh labeled "right pelvic lymph nodes" is an 8.3 x

5.0 x 2.4 cm aggregate of adipose and lymphatic tissue. Multiple

(24) lymph nodes are identified. All lymph nodes submitted.

D. Received fresh labeled "left pelvic lymph nodes" is a 7.3 x 4.6

x 1.8 cm aggregate of adipose and lymphatic tissue. Multiple (19)

lymph nodes are identified. All lymph nodes submitted.

Source: NCI Genomic Data Commons file 7f826456-6aee-4650-a90e-ce3f2c3dec52 (TCGA-D1-A1NS.FE397385-B600-4450-AE73-3CB62D5FEA3B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).